Somatic mutation profile of tumor specimen 416bb805-e4cd-4ca6-8fdd-1eec2d (aliquot 416bb805-e4cd-4ca6-8fdd-1eec2d_D6) from CPTAC case 05CO015, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 416bb805-e4cd-4ca6-8fdd-1eec2d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a2429da-b232-4a9c-bae0-e4c31ca8f57f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen aa1c4fc6-9d37-4816-bf95-3a19dc (Blood Derived Normal), aliquot aa1c4fc6-9d37-4816-bf95-3a19dc_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bcf3ca7-e7a4-41d3-be3d-257d31c522df

The open-access MAF lists 1,711 somatic variants for this specimen: 1,148 protein-altering or splice-affecting, 341 silent, 222 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 766, Silent 341, Frame Shift Del 259, Intron 108, Frame Shift Ins 49, 3'UTR 36, Nonsense Mutation 35, 5'UTR 32, RNA 22, Splice Site 14, Splice Region 12, 3'Flank 12.

Variants (750 of 1,711; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 59/366 reads (16%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- AR | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 216/575 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886041133, CM000310, CM102222, COSV65955765; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B2M | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 74/502 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1057519879, COSV62563048, COSV62563174, COSV62563707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1371del p.K457Nfs*17 | Frame Shift Del (DEL) | VAF 61/232 reads (26%) | catalogued as rs1085307340; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL1A1 | c.386del p.P129Lfs*136 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs72667014, CD063486, COSV99070635; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GNAS | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 122/775 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1131691999, CM013729, CM013730, COSV55691267; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.438del p.F146Lfs*26 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by mutect2, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 74/309 reads (24%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 44/229 reads (19%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A2M | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1259395599, COSV59385400; called by muse, mutect2, varscan2
- AAR2 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 121/451 reads (27%) | catalogued as rs374203470; called by muse, mutect2, varscan2
- ABCA13 | c.14186G>A p.R4729H | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs372286953, COSV68943281; called by muse, mutect2, varscan2
- ABCA4 | c.6074A>G p.E2025G | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs777410156; called by muse, mutect2, varscan2
- ABCA7 | c.1949_1951del p.F650del | In Frame Del (DEL) | VAF 40/234 reads (17%) | catalogued as rs763936445; called by pindel, varscan2
- ABCA7 | c.2959G>C p.E987Q | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1013655788; called by muse, mutect2, varscan2
- ABCC8 | c.2476G>T p.G826C | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56855212; called by mutect2, varscan2
- ABCD1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 198/557 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as COSV54384008, COSV99497984; called by muse, mutect2, varscan2
- AC098582.1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52026973; called by muse, mutect2
- ACVR2A | c.545del p.P182Hfs*6 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | catalogued as rs1406084229; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM21 | c.1177T>C p.C393R | Missense Mutation (SNP) | VAF 91/566 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462311574; called by muse, mutect2, varscan2
- ADAM29 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150256322; called by muse, mutect2
- ADAMTS6 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs145963490; called by muse, mutect2, varscan2
- ADGRD2 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs988949042; called by muse, mutect2, varscan2
- ADGRF1 | c.2536C>T p.R846* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as rs547714370; called by muse, mutect2, varscan2
- ADGRV1 | c.15271del p.Y5091Tfs*7 | Frame Shift Del (DEL) | VAF 78/511 reads (15%) | catalogued as rs1435790810; called by mutect2, pindel, varscan2
- ADRB1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV65167903; called by muse, mutect2
- AFAP1L1 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs374764113; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 38/233 reads (16%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- AGBL3 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as rs1262629816; called by muse, mutect2, varscan2
- AGO1 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs750172296, COSV64594905; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AIRE | c.336del p.R113Gfs*34 | Frame Shift Del (DEL) | VAF 59/347 reads (17%) | catalogued as COSV52397981; called by mutect2, pindel, varscan2
- ALDH16A1 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1172333251, COSV99512706; called by muse, mutect2, varscan2
- ALDH2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs940553638, COSV55665025; called by muse, mutect2
- ALDH3A1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs201594817; called by muse, varscan2
- ALOX12B | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028050037, CM103711; called by muse, mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 41/267 reads (15%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- ALS2 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs149670991, COSV51885571; called by muse, varscan2
- ANAPC7 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1251034723, COSV71443881; called by muse, mutect2, varscan2
- ANHX | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs532661509; called by muse, varscan2
- ANKRD11 | c.5810G>A p.G1937D | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.254); catalogued as rs762451759, COSV56365972; called by muse, mutect2, varscan2
- ANKRD33B | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1318760337; called by muse, mutect2
- ANKRD6 | c.2016del p.F672Lfs*34 (on ENST00000339746 / NM_001242809.2; = p.F667Lfs*34 on NM_014942.4) | Frame Shift Del (DEL) | VAF 22/146 reads (15%) | catalogued as rs751514998, COSV100329734; called by mutect2, pindel, varscan2
- ANO9 | c.1816G>A p.G606S | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1286350403, COSV100230124; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | catalogued as rs759218332; called by mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 24/212 reads (11%) | catalogued as rs3215969; called by mutect2, varscan2
- ARFGEF1 | c.5195G>A p.R1732H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51602818; called by muse, mutect2, varscan2
- ARFGEF2 | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs937998574; called by muse, mutect2
- ARHGAP22 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1309338429, COSV50942192; called by muse, mutect2, varscan2
- ARHGEF16 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV65681503; called by muse, mutect2
- ARHGEF4 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as rs527734596; called by muse, mutect2, varscan2
- ARSG | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs372096059; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 52/360 reads (14%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSL | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 41/616 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1157534083; called by muse, mutect2
- ASB2 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.396); catalogued as COSV60113886; called by muse, mutect2, varscan2
- ASNS | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.369); catalogued as rs753908207; called by muse, mutect2, varscan2
- ASPHD1 | c.99del p.S34Afs*33 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as COSV58103509; called by mutect2, pindel, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as rs771531141; called by mutect2, varscan2
- ATM | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as rs200601781, COSV99592134; ClinVar: not provided / likely benign / uncertain significance; called by muse, mutect2, varscan2
- ATM | c.5849C>T p.A1950V | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53725156; called by muse, mutect2, varscan2
- ATP10B | c.3140G>A p.R1047H | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.579); catalogued as rs757231042, COSV59165900; called by muse, mutect2, varscan2
- ATP11A | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV99370258; called by muse, mutect2, varscan2
- ATP13A1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs768339809; called by muse, mutect2, varscan2
- ATP4A | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs781628677, COSV52865764; called by muse, varscan2
- ATP6V1FNB | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1379417248; called by muse, mutect2
- ATXN7 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338151694; called by muse, mutect2, varscan2
- B4GALNT4 | c.918dup p.R307Afs*98 | Frame Shift Ins (INS) | VAF 20/172 reads (12%) | catalogued as rs770737105; called by mutect2, varscan2
- BAG6 | c.1930G>A p.A644T (on ENST00000676571; = p.A597T on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1436891981; called by muse, mutect2, varscan2
- BMS1 | c.3467G>T p.R1156M | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs978632695; called by muse, mutect2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BOLA3 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1487411769; called by muse, mutect2, varscan2
- BRCA2 | c.9981dup p.F3328Ifs*3 | Frame Shift Ins (INS) | VAF 37/253 reads (15%) | catalogued as rs1328254546; called by mutect2, pindel, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 20/102 reads (20%) | catalogued as rs749043197; called by mutect2, varscan2
- BRPF1 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs1188456016; called by muse, mutect2
- C16orf96 | c.1987C>A p.L663M | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV71472240; called by mutect2, varscan2
- C1QTNF5 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447464669; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- C2orf73 | c.622dup p.T208Nfs*28 | Frame Shift Ins (INS) | VAF 22/154 reads (14%) | catalogued as rs772729186, COSV58310692; called by mutect2, varscan2
- C8orf89 | c.457del p.S153Afs*16 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs951061763; called by mutect2, varscan2
- CA3 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 26/171 reads (15%) | catalogued as rs746057618; called by muse, mutect2, varscan2
- CABS1 | c.215del p.K72Rfs*28 | Frame Shift Del (DEL) | VAF 30/196 reads (15%) | catalogued as rs757778717, COSV99909153; called by mutect2, pindel, varscan2
- CABS1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1200200572; called by muse, mutect2, varscan2
- CACNA1D | c.2524G>A p.G842R (on ENST00000350061 / NM_001128840.3; = p.G862R on NM_000720.4) | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs760959586, COSV99052026; called by muse, mutect2, varscan2
- CACNB2 | c.505G>A p.E169K (on ENST00000324631 / NM_201596.3; = p.E114K on NM_000724.4) | Missense Mutation (SNP) | VAF 66/461 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV56651315; called by muse, mutect2, varscan2
- CAMKK2 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202048546, COSV61216310; called by muse, mutect2, varscan2
- CAMTA2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs756928273; called by mutect2, varscan2
- CARS2 | c.1006del p.S336Pfs*46 | Frame Shift Del (DEL) | VAF 22/115 reads (19%) | catalogued as rs1371294262; called by mutect2, pindel, varscan2
- CBFA2T2 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs767847707; called by muse, mutect2, varscan2
- CBLC | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.478); catalogued as COSV54322801; called by muse, mutect2, varscan2
- CBY2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 71/401 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60117963, COSV60118038; called by muse, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC151 | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.655); catalogued as rs770604833; called by muse, mutect2, varscan2
- CCDC158 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 96/500 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs748109867, COSV66355826; called by muse, mutect2, varscan2
- CCDC175 | c.1895del p.N632Tfs*8 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | catalogued as rs1198843594; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs747079826; called by mutect2, varscan2
- CCR9 | c.188C>T p.A63V (on ENST00000357632 / NM_031200.3; = p.A51V on NM_006641.4) | Missense Mutation (SNP) | VAF 83/436 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1049322967; called by muse, varscan2
- CD79A | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55738150; called by mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 27/137 reads (20%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH23 | c.3163G>A p.V1055M | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs747028795, COSV54923496; ClinVar: uncertain significance; called by muse, mutect2
- CEP192 | c.5542C>T p.R1848* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as rs765076361, COSV100381537, COSV58066045; called by muse, mutect2, varscan2
- CEP350 | c.6232del p.R2078Gfs*6 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs759430139; called by mutect2, pindel, varscan2
- CFAP100 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs371120376, COSV61503123; called by muse, mutect2, varscan2
- CFAP53 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 38/298 reads (13%) | catalogued as rs777253347; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 72/278 reads (26%) | catalogued as rs778664468; called by mutect2, varscan2
- CGN | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs931963460, COSV54973984; called by muse, mutect2, varscan2
- CHAF1A | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573779621, COSV100011346; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHMP6 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751560399, COSV57328008; called by muse, mutect2, varscan2
- CHRM4 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.738); catalogued as COSV100642138; called by muse, mutect2, varscan2
- CIC | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 56/323 reads (17%) | catalogued as rs968289754, COSV50569160; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs763852712; called by mutect2, varscan2
- CLEC14A | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs757345305; called by muse, mutect2, varscan2
- CLEC18B | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 43/922 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1467797766; called by muse, mutect2
- CMTM1 | c.180del p.F60Lfs*3 (on ENST00000457188 / NM_181269.3; = p.F177Lfs*3 on NM_052999.4) | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | catalogued as rs773521289; called by mutect2, varscan2
- CNBD1 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1448245838; called by muse, mutect2, varscan2
- CNTN2 | c.2662G>A p.V888M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs775579054, COSV59351864; ClinVar: uncertain significance; called by mutect2, varscan2
- CNTNAP3 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1322493756; called by muse, mutect2, varscan2
- CNTROB | c.2699del p.G900Efs*34 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs35508310, COSV66608279; called by mutect2, varscan2
- COIL | c.192del p.L65Sfs*11 | Frame Shift Del (DEL) | VAF 27/166 reads (16%) | catalogued as rs763239843; called by mutect2, pindel, varscan2
- COL26A1 | c.648del p.S218Lfs*131 (on ENST00000313669 / NM_001278563.3; = p.S216Lfs*131 on NM_133457.4) | Frame Shift Del (DEL) | VAF 36/116 reads (31%) | catalogued as rs762324149; called by mutect2, varscan2
- COL4A5 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60369473; called by muse, mutect2
- COX15 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs371107669; called by muse, varscan2
- CPAMD8 | c.3737C>T p.A1246V (on ENST00000651564; = p.A1199V on NM_015692.5) | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs766475107; called by muse, mutect2, varscan2
- CPT1B | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs377484724; called by muse, mutect2, varscan2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 69/393 reads (18%) | catalogued as COSV51715473; called by mutect2, varscan2
- CRIP2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs587754581; called by mutect2, varscan2
- CROCC | c.1786A>G p.S596G | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100978049; called by muse, varscan2
- CRTC1 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV58719084; called by muse, mutect2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | catalogued as rs747248693; called by mutect2, varscan2
- CSMD3 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 68/449 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs779995662, COSV99852484; called by muse, mutect2, varscan2
- CTC1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 20/144 reads (14%) | catalogued as rs1169567839, COSV59853165; called by muse, mutect2, varscan2
- CTSL | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100446612; called by muse, mutect2, varscan2
- CTU2 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.057); catalogued as rs374137025; called by muse, mutect2, varscan2
- DAPK2 | c.1033-7del | Splice Region (DEL) | VAF 10/52 reads (19%) | catalogued as rs753638020; called by mutect2, varscan2
- DCAF11 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs776938647, COSV58108562; called by muse, mutect2, varscan2
- DDX23 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57284011; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs772416332; called by mutect2, varscan2
- DECR2 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs770515810; called by muse, mutect2, varscan2
- DENR | c.323del p.K108Rfs*10 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | catalogued as rs1566061026; called by mutect2, pindel
- DHTKD1 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.283); catalogued as rs760006425; called by muse, mutect2, varscan2
- DHX16 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757748798, COSV64564008; called by muse, mutect2, varscan2
- DHX29 | c.222T>A p.D74E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.182); catalogued as rs1246319884; called by muse, mutect2
- DIDO1 | c.4550C>T p.S1517L | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs778919517, COSV99825806; called by muse, mutect2, varscan2
- DISP3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1017077881; called by muse, mutect2, varscan2
- DKK1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138015066; called by muse, varscan2
- DLX3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1032099378, COSV71547429; called by muse, mutect2, varscan2
- DNAH5 | c.6373A>G p.I2125V | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV54223987; called by muse, mutect2, varscan2
- DNAH9 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV52352887, COSV52376688; called by muse, mutect2, varscan2
- DNAJC13 | c.3051G>A p.W1017* | Nonsense Mutation (SNP) | VAF 25/209 reads (12%) | catalogued as COSV99606826; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs1239294263; called by mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 47/388 reads (12%) | catalogued as rs35482889; called by mutect2, varscan2
- DUOX1 | c.2303del p.F768Sfs*31 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as COSV58477256; called by mutect2, pindel
- EDEM2 | c.1410del p.Y471Tfs*21 | Frame Shift Del (DEL) | VAF 86/288 reads (30%) | catalogued as rs767540719; called by mutect2, varscan2
- EEF1AKMT4 | c.538del p.H180Tfs*16 | Frame Shift Del (DEL) | VAF 28/154 reads (18%) | catalogued as COSV56181776; called by mutect2, pindel, varscan2
- EFCAB12 | c.1035G>A p.K345= | Splice Region (SNP) | VAF 20/186 reads (11%) | catalogued as COSV58176897; called by muse, mutect2, varscan2
- EGR3 | c.1128dup p.V377Rfs*30 | Frame Shift Ins (INS) | VAF 20/158 reads (13%) | catalogued as rs749768945; called by mutect2, pindel
- EHMT1 | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs376628665; ClinVar: likely benign; called by muse, mutect2
- EIF2AK2 | c.1227del p.K409Nfs*2 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs1314347511; called by mutect2, pindel
- ELMO3 | c.1237C>T p.R413C (on ENST00000652269; = p.R360C on NM_024712.5) | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs370040668; called by muse, mutect2, varscan2
- ENOX1 | c.308del p.P103Hfs*12 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as COSV54906833; called by mutect2, pindel, varscan2
- ENPP4 | c.1338T>A p.D446E | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV58089068; called by muse, mutect2, varscan2
- EPB41L1 | c.1568G>T p.S523I | Missense Mutation (SNP) | VAF 41/410 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52436010; called by mutect2, varscan2
- EPX | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.323); catalogued as rs756362103, COSV56598674; called by muse, mutect2, varscan2
- ERBB4 | c.119_120dup p.D41Lfs*26 | Frame Shift Ins (INS) | VAF 48/396 reads (12%) | catalogued as COSV53588699; called by mutect2, varscan2
- EVI5 | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199524271; called by muse, mutect2, varscan2
- EXOC2 | c.25dup p.L9Pfs*9 | Frame Shift Ins (INS) | VAF 26/132 reads (20%) | catalogued as rs748159069; called by mutect2, varscan2
- FAM102A | c.1082C>T p.T361M (on ENST00000373095 / NM_001035254.3; = p.T219M on NM_203305.2) | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs149291532; called by muse, mutect2, varscan2
- FAM110C | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1412530671, COSV100566881, COSV59655660; called by muse, mutect2, varscan2
- FAM13A | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs755118899; called by muse, mutect2, varscan2
- FAM155B | c.554del p.N185Tfs*40 | Frame Shift Del (DEL) | VAF 26/261 reads (10%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM160A2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 40/244 reads (16%) | catalogued as rs1564866543, COSV56412559; called by muse, mutect2, varscan2
- FAM161B | c.255del p.E86Sfs*35 (on ENST00000651776; = p.E23Sfs*35 on NM_152445.3) | Frame Shift Del (DEL) | VAF 23/154 reads (15%) | catalogued as rs775951198; called by mutect2, varscan2
- FAM47B | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV61455930; called by muse, mutect2, varscan2
- FASTKD5 | c.1979A>G p.K660R | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs369758244; called by muse, mutect2
- FAT4 | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs569440986, COSV101272670; called by muse, mutect2, varscan2
- FBXL16 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770520626, COSV60963966; called by muse, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXW12 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs148596796, COSV56484212; called by muse, mutect2, varscan2
- FGD3 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767400375; called by muse, mutect2, varscan2
- FHOD1 | c.2225C>T p.T742M | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs750497587, COSV50770793; called by muse, mutect2, varscan2
- FHOD1 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); catalogued as rs773047427; called by muse, mutect2, varscan2
- FJX1 | c.802del p.L268Sfs*19 | Frame Shift Del (DEL) | VAF 52/288 reads (18%) | catalogued as rs771587869; called by mutect2, pindel, varscan2
- FLNC | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 210/677 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1345929888; ClinVar: uncertain significance; called by mutect2, varscan2
- FLT4 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs768687155, COSV99985814; called by muse, mutect2
- FOXB1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1490898774, COSV68525750; called by muse, mutect2, varscan2
- FOXD4 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 149/876 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs957694320; called by muse, mutect2, varscan2
- FUT11 | c.880_881del p.W294Afs*31 | Frame Shift Del (DEL) | VAF 32/228 reads (14%) | catalogued as rs1190336004; called by pindel, varscan2
- FUT5 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 107/649 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs769020990; called by muse, mutect2, varscan2
- FZR1 | c.1124dup p.G376Rfs*4 | Frame Shift Ins (INS) | VAF 39/211 reads (18%) | catalogued as rs1350973455; called by mutect2, pindel, varscan2
- GAL3ST1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs767295908; called by muse, mutect2, varscan2
- GDPD2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs149119501, COSV100978533; called by muse, mutect2, varscan2
- GLDC | c.3053C>T p.A1018V | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as rs150149798; called by muse, mutect2, varscan2
- GML | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs762771971, COSV55278123, COSV99638728; called by muse, mutect2, varscan2
- GNA15 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as COSV53587335; called by muse, mutect2
- GNPTG | c.514del p.H172Tfs*4 | Frame Shift Del (DEL) | VAF 97/477 reads (20%) | catalogued as rs1321245057; called by mutect2, pindel, varscan2
- GPR142 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 77/443 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs370594794, COSV100170775; called by muse, mutect2, varscan2
- GPR63 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013119; called by muse, mutect2, varscan2
- GRB10 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 88/425 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs756517889, COSV60007087; called by muse, mutect2, varscan2
- GREM2 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs763116778; called by muse, mutect2, varscan2
- GRID1 | c.1289T>C p.M430T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs770513124; called by muse, mutect2, varscan2
- GRIPAP1 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1284469158, COSV64551985; called by muse, mutect2, varscan2
- GUCY2D | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1202782880; called by muse, mutect2, varscan2
- HCAR2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 79/541 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as rs201770856, COSV61024683; called by muse, mutect2, varscan2
- HEATR9 | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161041119; called by muse, mutect2
- HERC2 | c.4519G>A p.A1507T | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as rs1184583478, COSV55315251, COSV99870702; called by muse, mutect2, varscan2
- HIC1 | c.346G>A p.A116T (on ENST00000322941 / NM_001098202.1; = p.A97T on NM_006497.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.989); catalogued as rs1325649654, COSV53966356; called by muse, mutect2
- HIGD2B | c.57dup p.I20Hfs*3 | Frame Shift Ins (INS) | VAF 18/128 reads (14%) | catalogued as rs771338686; called by mutect2, pindel, varscan2
- HIVEP3 | c.2830A>G p.S944G | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs766254631; called by muse, mutect2, varscan2
- HIVEP3 | c.1660del p.H554Tfs*20 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs1558087190; called by pindel, varscan2
- HK1 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs768316984; called by muse, mutect2, varscan2
- HK1 | c.1927del p.R643Gfs*20 | Frame Shift Del (DEL) | VAF 48/299 reads (16%) | catalogued as COSV53856274; called by mutect2, pindel, varscan2
- HMGCR | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1321843698; called by muse, mutect2
- HOXB13 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs546307661, COSV51706631, COSV99285134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXC4 | c.756del p.P253Rfs*15 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as COSV57699824; called by mutect2, pindel
- HPS4 | c.1909C>T p.H637Y | Missense Mutation (SNP) | VAF 98/495 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753017691; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM5 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1472450876; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 94/540 reads (17%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IFT172 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs371919234; called by muse, mutect2, varscan2
- IGDCC3 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs372129215; called by muse, mutect2
- IGHV3-15 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 58/365 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.681); catalogued as rs541148548; called by muse, mutect2, varscan2
- IL20RA | c.1529A>G p.D510G | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1562226228, COSV57361172; called by muse, mutect2
- IL21R | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as rs1473052912; called by muse, mutect2, varscan2
- IL3RA | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.207); catalogued as rs746515284; called by muse, mutect2, varscan2
- INHBA | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV54221516; called by muse, mutect2, varscan2
- INPP5J | c.2804del p.G935Afs*32 (on ENST00000331075 / NM_001284285.2; = p.G567Afs*32 on NM_001002837.2) | Frame Shift Del (DEL) | VAF 32/190 reads (17%) | catalogued as rs1569291476; called by mutect2, pindel, varscan2
- INTS1 | c.5281C>T p.R1761W | Missense Mutation (SNP) | VAF 41/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs996774777; called by muse, mutect2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- INVS | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs984016152, COSV52443366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IPO11 | c.1175-1G>A p.X392_splice | Splice Site (SNP) | VAF 24/94 reads (26%) | catalogued as rs775758934; called by muse, mutect2, varscan2
- IRAG1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs755206470, COSV70210842; called by muse, mutect2, varscan2
- IRS1 | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs150039193; called by muse, mutect2, varscan2
- ITGA2B | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 89/472 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs571678984, COSV99289396; called by muse, mutect2, varscan2
- ITGA7 | c.2974C>T p.L992= (on ENST00000555728; = p.L948= on NM_002206.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 90/649 reads (14%) | catalogued as COSV57698029; called by muse, mutect2, varscan2
- KASH5 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as rs779024223; called by muse, mutect2, varscan2
- KAT6B | c.6146C>T p.T2049M | Missense Mutation (SNP) | VAF 73/441 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV54744693; called by muse, mutect2, varscan2
- KCNA3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63900831; called by muse, mutect2
- KCNC3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100979141; called by muse, mutect2, varscan2
- KCNH4 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as rs1371556166, COSV99237144; called by muse, mutect2, varscan2
- KCTD10 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs373818598; called by muse, mutect2, varscan2
- KIAA2012 | c.2523del p.K841Nfs*2 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs760609491; called by mutect2, varscan2
- KIDINS220 | c.4657C>T p.P1553S | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs375631503; called by muse, mutect2, varscan2
- KIF21B | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs760774571; called by muse, mutect2, varscan2
- KIF26A | c.1934C>A p.A645D | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100181127; called by mutect2, varscan2
- KIRREL3 | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746710047; called by muse, mutect2, varscan2
- KLHDC9 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs1362909325; called by muse, mutect2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KMT2C | c.4116_4118del p.L1373del | In Frame Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs761000251; called by pindel, varscan2
- KMT5B | c.1166dup p.N389Kfs*6 (on ENST00000304363 / NM_001300907.1; = p.N389Kfs*5 on NM_016028.4) | Frame Shift Ins (INS) | VAF 41/198 reads (21%) | catalogued as rs1434065199; called by mutect2, varscan2
- KRT86 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs1397640624; called by muse, mutect2, varscan2
- KSR1 | c.872dup p.P292Tfs*22 (on ENST00000644974 / NM_001367810.1; = p.P155Tfs*22 on NM_014238.2) | Frame Shift Ins (INS) | VAF 23/84 reads (27%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA1 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 21/421 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355107542; called by muse, mutect2
- LAMA5 | c.10334G>A p.R3445Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs562544487; called by muse, mutect2, varscan2
- LAMB4 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV52723830; called by muse, mutect2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 42/290 reads (14%) | catalogued as rs782221297; called by pindel, varscan2
- LAS1L | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1001972342; called by muse, mutect2
- LCAT | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 122/479 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50452208; called by muse, mutect2, varscan2
- LHX1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1302408079; called by muse, mutect2, varscan2
- LILRA4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.34); catalogued as rs1002404506, COSV52490304, COSV52493488; called by muse, mutect2, varscan2
- LIMK1 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782494881, COSV60280324; called by muse, mutect2, varscan2
- LIN28A | c.206dup p.V70Sfs*9 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | catalogued as rs756465040; called by mutect2, pindel, varscan2
- LRIT1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs776031813, COSV100928008; called by muse, mutect2, varscan2
- LRIT1 | c.52del p.Q18Rfs*26 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as rs759958964; called by mutect2, pindel, varscan2
- LRP1 | c.9853C>T p.R3285C | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1327544994; called by muse, mutect2, varscan2
- LRP1 | c.11819G>A p.R3940H | Missense Mutation (SNP) | VAF 63/415 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs748150646; called by muse, mutect2, varscan2
- LRP1 | c.12575del p.P4192Qfs*150 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRC1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100906600; called by muse, mutect2, varscan2
- LRRC10 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as rs376496424, COSV104422072; called by muse, mutect2, varscan2
- LRRC10B | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV104429769; called by muse, mutect2, varscan2
- LRRC7 | c.3671C>T p.A1224V (on ENST00000651989 / NM_001370785.2; = p.A1191V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.432); catalogued as rs141951097; called by muse, mutect2
- LYST | c.8359-5del | Splice Region (DEL) | VAF 17/134 reads (13%) | catalogued as rs1411317089, COSV101090283; called by mutect2, pindel, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEE1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs782779173, COSV63909207; called by muse, mutect2, varscan2
- MAGEL2 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs764650142, COSV100045976; called by muse, mutect2, varscan2
- MAP3K2 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1280534973; called by muse, mutect2, varscan2
- MAP7D1 | c.1252_1254del p.K418del | In Frame Del (DEL) | VAF 18/122 reads (15%) | catalogued as rs752518838; called by pindel, varscan2
- MARCHF4 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410905109, COSV56107808; called by muse, mutect2, varscan2
- MARCHF9 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 22/151 reads (15%) | catalogued as rs1376654148; called by muse, mutect2, varscan2
- MEOX2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1421793823, COSV100012491, COSV56287804; called by muse, mutect2, varscan2
- METAP2 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200035170; called by muse, mutect2, varscan2
- MFN1 | c.401del p.K134Rfs*3 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | catalogued as rs755881517; called by mutect2, varscan2
- MFN2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 92/537 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs368032696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as rs751944867; called by mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 70/217 reads (32%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MLKL | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 13/150 reads (9%) | catalogued as rs994770593, COSV58205710; called by muse, mutect2
- MMP23B | c.912del p.R305Gfs*13 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | catalogued as rs1251889010; called by mutect2, pindel, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 47/250 reads (19%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRO | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370546021; called by muse, mutect2, varscan2
- MRPS12 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.225); catalogued as rs143918075; called by muse, mutect2, varscan2
- MSTO1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs139011201; called by muse, mutect2, varscan2
- MTERF3 | c.635del p.N212Ifs*12 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as COSV54632210; called by mutect2, pindel, varscan2
- MTMR7 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs750007122, COSV51665864; called by muse, mutect2, varscan2
- MTUS2 | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1299956829; called by muse, mutect2, varscan2
- MUC2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs769910634; called by muse, mutect2
- MUC5B | c.12215G>A p.S4072N | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs377724360; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | catalogued as rs764857791; called by mutect2, varscan2
- MYBBP1A | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs574277551; called by muse, mutect2, varscan2
- MYO15A | c.2174del p.P725Lfs*3 | Frame Shift Del (DEL) | VAF 23/145 reads (16%) | catalogued as rs1218547077; called by mutect2, pindel, varscan2
- MYOCD | c.2345C>T p.S782L | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs376756900; called by muse, mutect2, varscan2
- MYOG | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1470567669; called by muse, mutect2
- MYOM3 | c.1994C>T p.T665M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs148441250, COSV58394688; called by muse, mutect2, varscan2
- MYT1 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs755177120; called by muse, mutect2, varscan2
- MYT1L | c.1497G>T p.K499N | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67707758, COSV67722818; called by muse, mutect2, varscan2
- MZF1 | c.247A>G p.M83V | Missense Mutation (SNP) | VAF 102/487 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs779742337; called by muse, mutect2, varscan2
- NALCN | c.4403G>A p.R1468H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as COSV51916921; called by muse, mutect2, varscan2
- NAP1L4 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as rs1365839362; called by muse, mutect2, varscan2
- NAPRT | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1205877026, COSV99434276; called by muse, mutect2, varscan2
- NCDN | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV57845382; called by muse, mutect2, varscan2
- NCOA3 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 21/402 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1172968588, COSV59072449; called by muse, mutect2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs747914168; called by mutect2, varscan2
- NEB | c.8039G>A p.R2680Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs201746137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEDD4 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); catalogued as COSV59058813; called by muse, mutect2, varscan2
- NELL2 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV61582318; called by muse, varscan2
- NEURL4 | c.620del p.P207Lfs*69 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | catalogued as COSV59760956; called by mutect2, varscan2
- NHS | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372969054, COSV66284808; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NID2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs759815670, COSV53495297, COSV53504393; called by muse, mutect2, varscan2
- NIN | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as rs1566829394, COSV55408940; called by muse, varscan2
- NKAP | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV65056242; called by muse, mutect2, varscan2
- NOD2 | c.1065G>A p.W355* | Nonsense Mutation (SNP) | VAF 200/1149 reads (17%) | catalogued as rs104895488, CM082983; ClinVar: not provided; called by muse, mutect2, varscan2
- NOMO2 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769388876; called by muse, mutect2, varscan2
- NOP2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs773963391; called by muse, mutect2, varscan2
- NOTCH3 | c.6238C>T p.R2080W | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs113178142, COSV54650568; called by muse, mutect2, varscan2
- NPHS1 | c.2132G>C p.R711P | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as CM1311265; called by muse, mutect2
- NR5A1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs944569341, COSV65294925; called by muse, mutect2, varscan2
- NSUN2 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs907364994, COSV52955203, COSV99243130; called by muse, mutect2, varscan2
- NUDT1 | c.354del p.V119Wfs*76 (on ENST00000397048 / NM_198952.1; = p.V96Wfs*76 on NM_002452.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 36/354 reads (10%) | catalogued as rs775493463; called by mutect2, pindel, varscan2
- NUDT18 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1177210217; called by muse, mutect2, varscan2
- NUP205 | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs762476152; called by muse, mutect2, varscan2
- OBSCN | c.18277G>A p.A6093T | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs752840470; called by muse, mutect2, varscan2
- OGA | c.351G>A p.E117= | Splice Region (SNP) | VAF 6/37 reads (16%) | catalogued as rs1256665302; called by muse, mutect2, varscan2
- OLFM2 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749684075, COSV53430107; called by muse, mutect2, varscan2
- OPRK1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV55569154; called by muse, mutect2, varscan2
- OR1L4 | c.460C>A p.H154N | Missense Mutation (SNP) | VAF 54/440 reads (12%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.644); catalogued as COSV99413840; called by mutect2, varscan2
- OSBPL11 | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779271741; called by muse, mutect2, varscan2
- P3H4 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV58636721; called by muse, mutect2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 50/300 reads (17%) | catalogued as rs763394045; called by mutect2, varscan2
- PACS2 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs781868356, COSV57657333, COSV99051049; called by muse, mutect2, varscan2
- PAK6 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs746529258, COSV99545235; called by muse, mutect2, varscan2
- PARP12 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 85/306 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1363060395; called by muse, mutect2, varscan2
- PARP12 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370881268; called by muse, mutect2
- PATZ1 | c.1036del p.R346Efs*83 | Frame Shift Del (DEL) | VAF 51/274 reads (19%) | catalogued as COSV99315665; called by mutect2, pindel, varscan2
- PAX1 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.197); catalogued as rs772608979; called by muse, mutect2, varscan2
- PCDH11X | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 60/492 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV53468106; called by mutect2, varscan2
- PCDHA9 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 157/804 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as rs782481269, COSV65330637; called by muse, mutect2, varscan2
- PCDHB11 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 146/1061 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); catalogued as rs1554285611; called by muse, varscan2
- PCDHB14 | c.1202del p.F401Sfs*3 | Frame Shift Del (DEL) | VAF 41/305 reads (13%) | catalogued as COSV53387937; called by mutect2, pindel, varscan2
- PCDHB6 | c.1682A>G p.Y561C | Missense Mutation (SNP) | VAF 32/832 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50720831; called by muse, mutect2
- PCDHGA5 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs867970296, COSV53898902; called by muse, mutect2
- PCLO | c.3719del p.K1240Sfs*78 | Frame Shift Del (DEL) | VAF 16/165 reads (10%) | catalogued as COSV61638231; called by mutect2, pindel
- PCNX1 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 63/345 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.993); catalogued as rs1243081629; called by muse, mutect2, varscan2
- PCNX4 | c.793G>A p.D265N (on ENST00000406854 / NM_001330177.2; = p.D31N on NM_022495.5) | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372294775; called by muse, varscan2
- PCYT2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776766776; called by muse, mutect2, varscan2
- PDZD7 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200730376; called by muse, mutect2, varscan2
- PEX10 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.255); catalogued as rs1226924524; called by muse, mutect2, varscan2
- PFN3 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs775905615; called by muse, mutect2, varscan2
- PGBD5 | c.895G>A p.A299T (on ENST00000525115; = p.A368T on NM_001258311.2) | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs371374137; called by muse, mutect2, varscan2
- PGF | c.609-1G>A p.X203_splice (on ENST00000405431; = p.X131_splice on NM_002632.5) | Splice Site (SNP) | VAF 21/132 reads (16%) | catalogued as rs1378249004, COSV99462856; called by muse, mutect2, varscan2
- PHF12 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs773982324; called by muse, mutect2, varscan2
- PIEZO1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs1043456779, COSV56336206; called by muse, mutect2, varscan2
- PIGQ | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780359107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIGT | c.1730del p.P577Hfs*67 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | catalogued as rs760395465; called by mutect2, pindel, varscan2
- PIK3CB | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs143122477, COSV56686785; called by muse, mutect2, varscan2
- PLCL2 | c.2885C>T p.A962V (on ENST00000615277 / NM_001144382.2; = p.A836V on NM_015184.5) | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as rs775729111, COSV67625912; called by muse, mutect2, varscan2
- PLEKHB2 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as COSV100389047; called by muse, mutect2, varscan2
- PLEKHD1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as rs545252455; called by muse, mutect2, varscan2
- PLEKHG4B | c.46G>T p.A16S (on ENST00000283426; = p.A372S on NM_052909.5) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1345727903; called by muse, mutect2, varscan2
- PLEKHM3 | c.1960G>T p.G654* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV66816325; called by mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs761459630; called by mutect2, varscan2
- POLD1 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1060501818, COSV54530392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARG | c.142G>A p.V48M (on ENST00000287820 / NM_015869.5; = p.V18M on NM_005037.7) | Missense Mutation (SNP) | VAF 63/411 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs141797536; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 34/206 reads (17%) | catalogued as rs763475304; called by mutect2, varscan2
- PPP1R9B | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1180544842; called by muse, varscan2
- PPP2R3A | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV53860206; called by muse, mutect2, varscan2
- PPP2R3A | c.1951A>G p.T651A | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs773630044; called by muse, mutect2
- PPP4R4 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs749490429; called by muse, mutect2, varscan2
- PRKCD | c.1300del p.D434Tfs*2 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs1559629912, COSV57847601; called by mutect2, pindel, varscan2
- PRKDC | c.6892G>A p.E2298K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs781041217; called by muse, mutect2, varscan2
- PRM1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 128/779 reads (16%) | PolyPhen probably damaging (0.968); catalogued as rs150259080; called by muse, mutect2, varscan2
- PRMT7 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374317868, COSV59832913; called by muse, mutect2, varscan2
- PROSER1 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61488248, COSV61489732; called by muse, mutect2, varscan2
- PRPS1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 15/528 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV65054190; called by muse, mutect2
- PRR23A | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV67213574; called by muse, mutect2, varscan2
- PSD2 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 28/198 reads (14%) | catalogued as rs1331955140; called by muse, mutect2, varscan2
- PSMB11 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1229386682; called by muse, mutect2, varscan2
- PTGFRN | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241127058; called by muse, mutect2, varscan2
- PTPRS | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV53630078; called by muse, mutect2, varscan2
- PWP2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs200260801; called by muse, mutect2, varscan2
- PXDN | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs1014853591, COSV53230257, COSV53231780; called by muse, mutect2, varscan2
- RAB17 | c.580del p.D194Mfs*6 | Frame Shift Del (DEL) | VAF 13/123 reads (11%) | catalogued as rs749607650, COSV52815998; called by mutect2, pindel, varscan2
- RAB27B | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1184128382; called by muse, mutect2, varscan2
- RABEP2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs548800253; called by mutect2, varscan2
- RADIL | c.2489T>C p.V830A | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs373247351, COSV68204077; called by muse, mutect2, varscan2
- RAPGEF4 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs1261313905; called by muse, mutect2, varscan2
- RASA1 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs769775990, COSV57204743; called by muse, mutect2, varscan2
- RASGRF2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 61/477 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs376549001, COSV54133822; called by muse, mutect2, varscan2
- RAVER2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs760149805, COSV53807002; called by muse, mutect2, varscan2
- RBL2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756677584; called by muse, varscan2
- RBM26 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.953); catalogued as rs777201336; called by muse, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMX | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.499); catalogued as COSV100284901; called by muse, varscan2
- RECK | c.80del p.G27Afs*37 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | catalogued as rs1232892058; called by mutect2, varscan2
- RERE | c.3739G>A p.G1247R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs746770127; called by mutect2, varscan2
- RFWD3 | c.145del p.V49Yfs*12 | Frame Shift Del (DEL) | VAF 32/185 reads (17%) | catalogued as rs1436313275, COSV63098411; called by mutect2, varscan2
- RFX1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1034202672, COSV54333112; called by muse, mutect2
- RGS19 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs753155089, COSV58659237; called by muse, mutect2, varscan2
- RNF166 | c.574del p.D192Tfs*79 | Frame Shift Del (DEL) | VAF 25/120 reads (21%) | catalogued as rs1309481901; called by mutect2, pindel, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- RNF31 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as rs751266528, COSV53758739; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 13/130 reads (10%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | catalogued as rs752898741; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPTOR | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs774124294; called by muse, mutect2, varscan2
- RPUSD4 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs199877205; called by muse, mutect2, varscan2
- SC5D | c.39del p.F13Lfs*23 | Frame Shift Del (DEL) | VAF 71/324 reads (22%) | catalogued as rs1185907700; called by mutect2, varscan2
- SCRIB | c.3706C>A p.P1236T | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.197); catalogued as rs782502287; called by mutect2, varscan2
- SDCCAG8 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs1268810880; called by muse, mutect2
- SEMA3E | c.1675C>G p.R559G | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57084702; called by muse, mutect2, varscan2
- SEMA5B | c.2636C>T p.T879M | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs548945722, COSV52098695; called by muse, mutect2, varscan2
- SENP3 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99547978; called by muse, mutect2, varscan2
- SERPIND1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs990605037; called by muse, mutect2, varscan2
- SETD5 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs765891569, COSV56711478; called by muse, mutect2, varscan2
- SETDB1 | c.2625del p.C876Vfs*8 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as COSV99644797; called by mutect2, pindel, varscan2
- SFI1 | c.2837C>A p.A946D (on ENST00000400288 / NM_001007467.3; = p.A915D on NM_014775.4) | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs1197655377; called by muse, mutect2
- SGF29 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs781275887; called by muse, mutect2, varscan2
- SH3RF3 | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1483924081; called by mutect2, varscan2
- SIDT2 | c.470+1G>A p.X157_splice | Splice Site (SNP) | VAF 10/210 reads (5%) | catalogued as COSV54061804; called by muse, mutect2
- SLC12A5 | c.2639G>A p.R880H (on ENST00000454036 / NM_001134771.2; = p.R857H on NM_020708.5) | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750336750, COSV54793420, COSV54799761; called by muse, mutect2, varscan2
- SLC12A7 | c.3040G>A p.V1014I | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs376924487; called by muse, mutect2, varscan2
- SLC25A22 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 104/635 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762897089; called by muse, mutect2, varscan2
- SLC25A29 | c.355C>T p.R119W (on ENST00000359232 / NM_001039355.3; = p.R53W on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs1263310094; called by muse, mutect2, varscan2
- SLC35F3 | c.110C>T p.A37V (on ENST00000366617 / NM_001300845.1; = p.A106V on NM_173508.4) | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV64020315; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 26/136 reads (19%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A5 | c.2857del p.L953Cfs*16 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | catalogued as rs1320472237; called by mutect2, pindel, varscan2
- SLC52A2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs143091206; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A8 | c.1670del p.G557Vfs*38 | Frame Shift Del (DEL) | VAF 57/480 reads (12%) | catalogued as CM122262; called by mutect2, pindel, varscan2
- SLC8A1 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.293); catalogued as rs760942212, COSV60479502, COSV60482244; called by muse, mutect2
- SMC6 | c.1180del p.S394Vfs*20 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as rs761535042; called by mutect2, pindel, varscan2
- SMIM10 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 17/355 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1345209195; called by muse, mutect2
- SMPD1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774190691, COSV54968094; called by muse, mutect2, varscan2
- SON | c.4235C>T p.A1412V | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs755961084; called by muse, mutect2, varscan2
- SORL1 | c.4109G>A p.R1370H | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV52750689; called by muse, mutect2, varscan2
- SOS2 | c.2784dup p.G929Wfs*15 | Frame Shift Ins (INS) | VAF 16/84 reads (19%) | catalogued as rs1347298671; called by mutect2, varscan2
- SOX21 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65375177; called by muse, mutect2, varscan2
- SPEM2 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs117934604; called by muse, mutect2, varscan2
- SPG11 | c.5136G>A p.M1712I | Missense Mutation (SNP) | VAF 100/519 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs1294100489; called by muse, mutect2, varscan2
- SPIRE2 | c.1130A>G p.N377S | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs200940634; called by muse, mutect2, varscan2
- SPTBN1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs777810695, COSV61691150; called by muse, mutect2, varscan2
- STAM | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs370940096; called by muse, mutect2, varscan2
- STARD9 | c.4280dup p.I1428Nfs*10 | Frame Shift Ins (INS) | VAF 30/261 reads (11%) | catalogued as rs1178350631; called by mutect2, pindel, varscan2
- STMND1 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as rs913947127, COSV62991826; called by muse, mutect2, varscan2
- STXBP1 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 109/564 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141517655; called by muse, mutect2, varscan2
- SUPT20H | c.278G>A p.G93E (on ENST00000350612 / NM_001014286.3; = p.G94E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1416842927, COSV100634759; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs753462162; called by mutect2, varscan2
- SYCP2 | c.526del p.M176* | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs1346657016; called by mutect2, varscan2
- SYMPK | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs536424856, COSV55617205; called by muse, mutect2, varscan2
- SYN1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV55950869; called by muse, mutect2, varscan2
- SYN2 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.208); catalogued as rs904785696; called by muse, mutect2, varscan2
- TAAR2 | c.725C>T p.A242V (on ENST00000367931 / NM_001033080.1; = p.A197V on NM_014626.3) | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs751485156; called by muse, mutect2, varscan2
- TAB3 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1437623643; called by muse, mutect2, varscan2
- TACC2 | c.6713C>T p.T2238M (on ENST00000334433; = p.T316M on NM_006997.4) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs776111533; called by muse, mutect2, varscan2
- TAF5 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs996911577; called by muse, mutect2
- TAS2R42 | c.258_260del p.I86del | In Frame Del (DEL) | VAF 26/232 reads (11%) | catalogued as rs775769058; called by pindel, varscan2
- TBC1D19 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs149649528; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF20 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as rs781682890, COSV59489789; called by muse, mutect2, varscan2
- TDRD1 | c.2319del p.F773Lfs*11 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs1420178213; called by mutect2, pindel, varscan2
- TDRD12 | c.1790del p.N597Ifs*25 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs1052864503; called by mutect2, varscan2
- TDRD12 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.162); catalogued as rs572487392; called by muse, mutect2, varscan2
- TDRD5 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 51/348 reads (15%) | catalogued as COSV54242009; called by muse, mutect2, varscan2
- TEAD1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57567252; called by muse, mutect2, varscan2
- TECTA | c.4385G>A p.R1462H | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs769069602, COSV50701567; called by muse, mutect2, varscan2
- TEP1 | c.5636C>T p.A1879V | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.393); catalogued as rs1248628899; called by muse, mutect2, varscan2
- TET1 | c.65del p.K22Rfs*23 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs1196853334; called by mutect2, varscan2
- TIGD4 | c.879T>G p.H293Q | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58550346; called by muse, mutect2
- TLR9 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs200200453, COSV100645784, COSV62345404; called by muse, mutect2, varscan2
- TMED8 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs976258674; called by muse, mutect2, varscan2
- TMEM132E | c.620G>A p.R207H (on ENST00000321639; = p.R297H on NM_001304438.2) | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.95); catalogued as rs916177288, COSV58696528; called by muse, mutect2, varscan2
- TMEM151B | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs993059057; called by muse, mutect2
- TMEM214 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs758813086, COSV53191850, COSV53192180; called by muse, mutect2, varscan2
- TNS1 | c.4109del p.P1370Rfs*84 | Frame Shift Del (DEL) | VAF 33/291 reads (11%) | catalogued as COSV50757551; called by mutect2, pindel, varscan2
- TNS2 | c.863G>A p.S288N (on ENST00000314250 / NM_170754.4; = p.S298N on NM_015319.2) | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.533); catalogued as COSV100048120; called by muse, mutect2, varscan2
- TOPAZ1 | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); catalogued as rs917089887; called by muse, mutect2, varscan2
- TOR4A | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778606281, COSV62626920; called by muse, mutect2, varscan2
- TRAF3 | c.416del p.N139Mfs*20 | Frame Shift Del (DEL) | VAF 36/290 reads (12%) | catalogued as rs1566789781; called by mutect2, pindel, varscan2
- TRDN | c.1050del p.E351Sfs*13 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | catalogued as rs753514580; called by mutect2, varscan2
- TRGV10 | c.346T>C p.W116R | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441847810; called by muse, mutect2, varscan2
- TRIM33 | c.503del p.G168Afs*11 | Frame Shift Del (DEL) | VAF 19/112 reads (17%) | catalogued as COSV100635817; called by mutect2, pindel, varscan2
- TRIO | c.3170C>T p.T1057M | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); catalogued as rs779211429; called by muse, mutect2, varscan2
- TRIO | c.7425del p.S2476Afs*51 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs774597492; ClinVar: uncertain significance; called by mutect2, pindel
- TRIOBP | c.6847G>C p.E2283Q (on ENST00000644935 / NM_001039141.3; = p.E570Q on NM_007032.5) | Missense Mutation (SNP) | VAF 22/730 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as rs924050978; called by muse, mutect2
- TRIP11 | c.4480C>T p.R1494* | Nonsense Mutation (SNP) | VAF 60/267 reads (22%) | catalogued as rs1024388083, COSV50916350, COSV99971086; called by muse, mutect2, varscan2
- TRPM3 | c.3703C>T p.R1235W (on ENST00000357533 / NM_001366142.2; = p.R1090W on NM_020952.6) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs777311611, COSV62585341; called by muse, mutect2
- TSPO | c.291del p.I98Sfs*32 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as COSV61568092; called by mutect2, pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.66445C>T p.R22149C (on ENST00000591111; = p.R14725C on NM_003319.4) | Missense Mutation (SNP) | VAF 79/287 reads (28%) | PolyPhen possibly damaging (0.87); catalogued as rs775743818; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | PolyPhen benign (0.216); catalogued as rs966391166; called by muse, mutect2
- TULP3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs17853063; called by muse, mutect2, varscan2
- TULP4 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753531085, COSV65574102; called by muse, mutect2, varscan2
- UBALD2 | c.452del p.G151Afs*58 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs1198314548; called by mutect2, pindel
- UBE2O | c.1121del p.N374Tfs*13 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | catalogued as rs1567834477; called by mutect2, pindel
- UBR1 | c.3310_3312del p.E1104del | In Frame Del (DEL) | VAF 50/294 reads (17%) | catalogued as rs1275821790; called by pindel, varscan2
- UBR4 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs750979993, COSV64391850, COSV64399060; called by muse, mutect2, varscan2
- UGP2 | c.1120dup p.A374Gfs*7 | Frame Shift Ins (INS) | VAF 34/268 reads (13%) | catalogued as rs769400835; called by mutect2, pindel, varscan2
- UGT1A6 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.562); catalogued as COSV59393165; called by muse, mutect2
- UGT8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs114818124; called by muse, mutect2, varscan2
- URGCP | c.954del p.S320Afs*16 (on ENST00000453200 / NM_001077663.3; = p.S311Afs*16 on NM_017920.4) | Frame Shift Del (DEL) | VAF 113/475 reads (24%) | catalogued as rs1562571872; called by mutect2, pindel, varscan2
- UROS | c.69A>C p.L23F | Missense Mutation (SNP) | VAF 65/357 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); catalogued as COSV100908879; called by muse, mutect2, varscan2
- USP9X | c.5070del p.F1690Lfs*8 | Frame Shift Del (DEL) | VAF 43/241 reads (18%) | catalogued as COSV100198262; called by mutect2, pindel, varscan2
- VAV2 | c.1678G>A p.G560R (on ENST00000371850 / NM_001134398.2; = p.G550R on NM_003371.4) | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs376689003; called by muse, mutect2, varscan2
- VPS16 | c.138del p.I47Lfs*4 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | catalogued as COSV66794871; called by mutect2, pindel, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs756221452; called by mutect2, varscan2
- VPS4B | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753852708, COSV53070198; called by muse, mutect2, varscan2
- WDR27 | c.2424+1G>A p.X808_splice | Splice Site (SNP) | VAF 18/106 reads (17%) | catalogued as rs1178691902; called by muse, mutect2, varscan2
- WDR76 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as rs755194035; called by muse, mutect2, varscan2
- XIRP2 | c.8249C>A p.S2750Y (on ENST00000628543; = p.S2925Y on NM_152381.6) | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.687); catalogued as COSV54691861, COSV54713165; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 71/357 reads (20%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBTB14 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs1235008040; called by muse, mutect2, varscan2
- ZBTB14 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV63696503; called by muse, mutect2, varscan2
- ZC3H4 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as rs375960398; called by muse, mutect2, varscan2
- ZC3H6 | c.588dup p.Q197Tfs*11 | Frame Shift Ins (INS) | VAF 18/132 reads (14%) | catalogued as rs750386324; called by mutect2, varscan2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | catalogued as rs760215323; called by mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | catalogued as rs753611080; called by mutect2, varscan2
- ZMYND15 | c.604dup p.L202Pfs*12 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | catalogued as rs1052556839; called by mutect2, pindel
- ZNF205 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.098); catalogued as COSV54621884; called by muse, mutect2, varscan2
- ZNF317 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 40/302 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs756486645, COSV56109502; called by muse, mutect2, varscan2
- ZNF407 | c.5510C>T p.A1837V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs988107151, COSV55245681; called by muse, mutect2, varscan2
- ZNF480 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 25/229 reads (11%) | catalogued as rs367935805; called by muse, mutect2, varscan2
- ZNF513 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 69/636 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs1360260017; called by muse, mutect2, varscan2
- ZNF521 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568023002, COSV64123636; called by muse, mutect2, varscan2
- ZNF549 | c.254C>T p.A85V (on ENST00000376233 / NM_001199295.2; = p.A72V on NM_153263.2) | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779093977, COSV53724117; called by muse, mutect2, varscan2
- ZNF585A | c.745A>G p.K249E (on ENST00000292841 / NM_001288800.2; = p.K194E on NM_152655.3) | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53067627; called by muse, mutect2, varscan2
- ZNF610 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs780673696, COSV58346295; called by muse, mutect2, varscan2
- ZNF641 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs1192838264; called by muse, varscan2
- ZNF646 | c.3803G>A p.R1268H | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1405409459; called by muse, mutect2, varscan2
- ZNF7 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as COSV57384375; called by muse, mutect2
- ZNF780B | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.958); catalogued as rs773391047; called by muse, mutect2, varscan2
- ZNF782 | c.1457C>A p.S486Y | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); catalogued as COSV56654745; called by muse, mutect2, varscan2
- ZNF789 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs370724585; called by muse, mutect2, varscan2
- ZSWIM5 | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs769955261, COSV99869899; called by muse, mutect2, varscan2
- ZZEF1 | c.5373del p.W1792Gfs*20 | Frame Shift Del (DEL) | VAF 23/150 reads (15%) | catalogued as rs1567797756; called by mutect2, pindel, varscan2
- A3GALT2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2
- ABCA12 | c.4853A>G p.Y1618C (on ENST00000272895 / NM_173076.3; = p.Y1300C on NM_015657.3) | Missense Mutation (SNP) | VAF 120/483 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.8971T>C p.W2991R | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC11 | c.3674C>A p.P1225Q | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AC055839.2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); called by muse, varscan2
- ACADL | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACAP3 | c.1819A>G p.S607G | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2
- ACBD3 | c.1519A>G p.K507E | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ACTG1 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 18/561 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ACTL7B | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ACTR5 | c.622T>C p.C208R | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- ACVR2B | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 94/487 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ADAM18 | c.2109C>A p.F703L | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS19 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADAMTSL2 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTSL2 | c.2179G>A p.V727I | Missense Mutation (SNP) | VAF 76/460 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by mutect2, varscan2
- ADAMTSL5 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ADARB1 | c.839A>T p.N280I | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADCK5 | c.583del p.H195Tfs*33 | Frame Shift Del (DEL) | VAF 91/364 reads (25%) | called by mutect2, pindel, varscan2
- ADCY1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADCY6 | c.2845C>T p.H949Y | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADH5 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ADORA1 | c.695T>A p.I232N | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AGAP5 | c.1187A>G p.H396R | Missense Mutation (SNP) | VAF 79/681 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 46/194 reads (24%) | called by mutect2, varscan2
- AGR3 | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- AHDC1 | c.1841A>G p.D614G | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AHSA1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- AHSP | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 80/454 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AKAP3 | c.1633del p.R545Gfs*22 | Frame Shift Del (DEL) | VAF 30/211 reads (14%) | called by mutect2, pindel, varscan2
- AKAP7 | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKNA | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- AKR1B1 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 73/430 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, varscan2
- ALAS1 | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- ALPK3 | c.2304del p.K768Nfs*12 | Frame Shift Del (DEL) | VAF 30/177 reads (17%) | called by mutect2, pindel, varscan2
- ANGEL2 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ANGPTL3 | c.222del p.K74Nfs*26 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- ANK3 | c.8251del p.I2751Yfs*21 | Frame Shift Del (DEL) | VAF 20/181 reads (11%) | called by mutect2, pindel, varscan2
- ANKAR | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ANLN | c.986T>C p.V329A | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- APBA3 | c.610del p.Q204Rfs*60 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, varscan2
- APC | c.3101_3107del p.E1034Gfs*20 | Frame Shift Del (DEL) | VAF 57/405 reads (14%) | called by mutect2, pindel, varscan2
- APC2 | c.3415del p.V1139Wfs*21 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- APCDD1 | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.425); called by muse, mutect2
- APOB | c.5294A>G p.D1765G | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ARAP2 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ARFGEF1 | c.3857C>T p.A1286V | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ARHGAP9 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ARHGEF10 | c.1783C>A p.L595M (on ENST00000398564; = p.L570M on NM_014629.4) | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF25 | c.1039-1G>T p.X347_splice | Splice Site (SNP) | VAF 42/238 reads (18%) | called by mutect2, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 26/219 reads (12%) | called by mutect2, pindel, varscan2
- ARID1A | c.6176del p.N2059Tfs*76 | Frame Shift Del (DEL) | VAF 73/384 reads (19%) | called by mutect2, pindel, varscan2
- ARID3C | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ARL13B | c.543del p.G182Afs*16 (on ENST00000394222 / NM_001174150.2; = p.G75Afs*16 on NM_144996.4) | Frame Shift Del (DEL) | VAF 46/246 reads (19%) | called by mutect2, varscan2
- ARL13B | c.838del p.M280Wfs*10 (on ENST00000394222 / NM_001174150.2; = p.M173Wfs*10 on NM_144996.4) | Frame Shift Del (DEL) | VAF 19/172 reads (11%) | called by mutect2, pindel, varscan2
- ARMC4 | c.1730del p.G577Vfs*9 | Frame Shift Del (DEL) | VAF 34/234 reads (15%) | called by mutect2, pindel, varscan2
- ASB16 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ASMTL | c.1826del p.G609Vfs*22 | Frame Shift Del (DEL) | VAF 64/411 reads (16%) | called by mutect2, pindel, varscan2
- ATP10A | c.3612del p.T1205Pfs*4 | Frame Shift Del (DEL) | VAF 29/170 reads (17%) | called by mutect2, pindel, varscan2
- ATP2B4 | c.1724T>C p.M575T | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ATP2C1 | c.2339T>C p.L780P | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ATP6V1FNB | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- ATXN10 | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); called by muse, mutect2
- AUP1 | c.1221G>T p.Q407H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- AXL | c.2011C>G p.R671G (on ENST00000301178 / NM_021913.5; = p.R662G on NM_001699.6) | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B2M | c.276del p.T93Lfs*10 | Frame Shift Del (DEL) | VAF 88/468 reads (19%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BCAN | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL9L | c.1144del p.E382Rfs*81 | Frame Shift Del (DEL) | VAF 53/243 reads (22%) | called by mutect2, pindel, varscan2
- BCL9L | c.852del p.T285Pfs*7 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
- BCL9L | c.95dup p.A33Cfs*11 | Frame Shift Ins (INS) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- BMPER | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 74/483 reads (15%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMPR2 | c.222del p.D76Tfs*2 | Frame Shift Del (DEL) | VAF 43/285 reads (15%) | called by mutect2, pindel, varscan2
- BRF1 | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.348); called by mutect2, varscan2
- BRWD3 | c.3263+2T>C p.X1088_splice | Splice Site (SNP) | VAF 21/223 reads (9%) | called by muse, mutect2, varscan2
- BUD23 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- C17orf50 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- C1GALT1C1L | c.30del p.F10Lfs*13 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- C1orf167 | c.3236T>C p.V1079A | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- C2orf16 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- C2orf73 | c.855del p.K285Nfs*17 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- C6 | c.1704G>T p.W568C | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C9orf131 | c.940del p.L314Wfs*79 | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | called by pindel, varscan2
- CA9 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CACNA1A | c.4968G>A p.P1656= | Splice Region (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- CACNA1F | c.2316G>T p.K772N | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by mutect2, varscan2
- CACNA1I | c.2352del p.F784Lfs*63 | Frame Shift Del (DEL) | VAF 32/194 reads (16%) | called by mutect2, pindel, varscan2
- CACNA2D3 | c.2182C>A p.L728I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CACNB2 | c.506A>T p.E169V (on ENST00000324631 / NM_201596.3; = p.E114V on NM_000724.4) | Missense Mutation (SNP) | VAF 66/467 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CAPN15 | c.391_399del p.K131_E133del | In Frame Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, varscan2
- CAPN2 | c.1825-2A>G p.X609_splice | Splice Site (SNP) | VAF 23/131 reads (18%) | called by muse, varscan2
- CARMIL1 | c.3459G>T p.Q1153H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CASP12 | c.246dup p.Q83Tfs*9 | Frame Shift Ins (INS) | VAF 14/129 reads (11%) | called by mutect2, pindel, varscan2
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 182/687 reads (26%) | called by mutect2, pindel, varscan2
- CAVIN1 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CBARP | c.664A>G p.K222E (on ENST00000382477; = p.K202E on NM_152769.3) | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CCAR1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CCDC106 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CCDC22 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CCDC85A | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- CCN4 | c.488del p.P163Rfs*11 | Frame Shift Del (DEL) | VAF 81/434 reads (19%) | called by mutect2, pindel, varscan2
- CCN5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CCNK | c.336del p.K112Nfs*13 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel, varscan2
- CCSER1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.12); called by muse, mutect2
- CD58 | c.556_557del p.Q186Vfs*4 | Frame Shift Del (DEL) | VAF 44/248 reads (18%) | called by mutect2, pindel, varscan2
- CDON | c.1748T>C p.L583P | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDX4 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2
- CENPF | c.8869del p.S2957Afs*6 | Frame Shift Del (DEL) | VAF 52/288 reads (18%) | called by mutect2, pindel, varscan2
- CENPI | c.2219A>G p.H740R | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- CEP250 | c.5735A>C p.E1912A | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CEP350 | c.3369del p.K1123Nfs*10 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, varscan2
- CEP85L | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERCAM | c.1025G>A p.W342* | Nonsense Mutation (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- CHD1L | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD1L | c.2481del p.L829* | Frame Shift Del (DEL) | VAF 31/153 reads (20%) | called by mutect2, pindel, varscan2
- CHD7 | c.1953del p.D652Tfs*59 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, varscan2
- CHD7 | c.8753_8755del p.L2918del | In Frame Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- CHTF18 | c.857_858del p.F286Cfs*11 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- CILP2 | c.2222T>C p.V741A | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNFN | c.113-1G>T p.X38_splice | Splice Site (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- CNGA1 | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 75/418 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CNOT1 | c.3119T>C p.V1040A | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL10A1 | c.878del p.P293Qfs*14 | Frame Shift Del (DEL) | VAF 47/318 reads (15%) | called by mutect2, pindel, varscan2
- COL27A1 | c.870del p.T291Lfs*167 | Frame Shift Del (DEL) | VAF 32/201 reads (16%) | called by mutect2, pindel, varscan2
- COL6A3 | c.6806T>C p.L2269P | Missense Mutation (SNP) | VAF 118/471 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- COL6A5 | c.4881dup p.K1628Efs*54 | Frame Shift Ins (INS) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- COL6A6 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.133); called by mutect2, varscan2
- COX7B2 | c.160T>C p.W54R | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CPSF2 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CRY2 | c.1192del p.R398Gfs*14 | Frame Shift Del (DEL) | VAF 26/149 reads (17%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.6484G>A p.G2162S (on ENST00000520002; = p.G2161S on NM_033225.6) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSNK1D | c.886-5_886-3del | Splice Region (DEL) | VAF 49/282 reads (17%) | called by pindel, varscan2
- CUL9 | c.1301T>G p.L434R | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by mutect2, varscan2
- CYSRT1 | c.513del p.F172Sfs*84 (on ENST00000409414; = p.F132Sfs*84 on NM_199001.5) | Frame Shift Del (DEL) | VAF 44/221 reads (20%) | called by mutect2, varscan2
- DAAM2 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DBF4B | c.205del p.A69Pfs*8 | Frame Shift Del (DEL) | VAF 42/178 reads (24%) | called by mutect2, pindel, varscan2
- DCAF1 | c.2976del p.K992Nfs*16 | Frame Shift Del (DEL) | VAF 32/307 reads (10%) | called by mutect2, pindel, varscan2
- DDC | c.953del p.K318Rfs*5 | Frame Shift Del (DEL) | VAF 33/323 reads (10%) | called by mutect2, pindel
- DHX30 | c.2972T>C p.L991P (on ENST00000445061 / NM_138615.3; = p.L952P on NM_014966.3) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DHX9 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLC1 | c.3566C>T p.A1189V (on ENST00000276297 / NM_001348081.2; = p.A752V on NM_006094.5) | Missense Mutation (SNP) | VAF 28/584 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2
- DLGAP5 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DMXL1 | c.4819G>A p.G1607S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH10 | c.5953C>A p.L1985M (on ENST00000409039; = p.L1924M on NM_207437.3) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by mutect2, varscan2
- DNAH9 | c.6260T>G p.M2087R | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.163); called by mutect2, varscan2
- DNAJC16 | c.428del p.L143Yfs*8 | Frame Shift Del (DEL) | VAF 53/290 reads (18%) | called by mutect2, pindel, varscan2
- DNHD1 | c.5356G>A p.G1786S | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNHD1 | c.7138G>T p.G2380W | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSCAM | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 48/326 reads (15%) | called by mutect2, varscan2
- DST | c.13544T>C p.L4515S (on ENST00000361203 / NM_001374722.1; = p.L2103S on NM_015548.5) | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- DUOX2 | c.4157del p.G1386Afs*34 | Frame Shift Del (DEL) | VAF 72/404 reads (18%) | called by mutect2, varscan2
- DUSP12 | c.984A>T p.K328N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- DYNC1H1 | c.9086T>C p.L3029S | Missense Mutation (SNP) | VAF 26/731 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DYRK2 | c.1261del p.L421Sfs*14 (on ENST00000344096 / NM_006482.3; = p.L348Sfs*14 on NM_003583.4) | Frame Shift Del (DEL) | VAF 47/283 reads (17%) | called by mutect2, pindel, varscan2
- DZANK1 | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ECE2 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ECI2 | c.887C>T p.A296V (on ENST00000380118 / NM_206836.3; = p.A266V on NM_006117.2) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF1G | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EFCAB1 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EFCAB6 | c.3171G>T p.Q1057H | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- EHHADH | c.1431dup p.G478Wfs*38 | Frame Shift Ins (INS) | VAF 51/275 reads (19%) | called by mutect2, pindel, varscan2
- EIF3B | c.2010_2011del p.S671Lfs*5 | Frame Shift Del (DEL) | VAF 56/214 reads (26%) | called by pindel, varscan2
- EIF3D | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ELL2 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- EMC7 | c.467dup p.W157Lfs*25 | Frame Shift Ins (INS) | VAF 24/110 reads (22%) | called by mutect2, pindel, varscan2
- ENTPD6 | c.511T>G p.F171V | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EPC1 | c.551dup p.N184Kfs*23 | Frame Shift Ins (INS) | VAF 28/183 reads (15%) | called by mutect2, pindel, varscan2
- EPHA4 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- EPHX4 | c.1083del p.D362Ifs*12 | Frame Shift Del (DEL) | VAF 9/101 reads (9%) | called by mutect2, pindel
- EPS15L1 | c.1775dup p.S593Qfs*7 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- EPX | c.1441A>G p.M481V | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ERBB4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 125/466 reads (27%) | called by mutect2, pindel, varscan2
- ERICH6B | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ESRP1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ETNK2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EVC2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- F13A1 | c.643del p.Y215Mfs*28 | Frame Shift Del (DEL) | VAF 64/372 reads (17%) | called by mutect2, pindel, varscan2
- FAM149A | c.1831T>C p.W611R (on ENST00000356371 / NM_001367768.2; = p.W320R on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM155B | c.199del p.A67Pfs*8 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- FAM163B | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM205A | c.3546G>T p.Q1182H | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FAM3C | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FANCB | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 42/440 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.175); called by muse, mutect2
- FANCC | c.1474_1476del p.L492del | In Frame Del (DEL) | VAF 97/552 reads (18%) | called by pindel, varscan2
- FANCG | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAS | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.03); called by muse, mutect2
- FAT2 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.057); called by muse, mutect2
- FAT3 | c.12616G>A p.G4206S | Missense Mutation (SNP) | VAF 96/619 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FAT4 | c.9995A>G p.D3332G | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAT4 | c.14261G>T p.R4754I | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FBXO15 | c.696del p.K232Nfs*5 | Frame Shift Del (DEL) | VAF 35/185 reads (19%) | called by mutect2, pindel, varscan2
- FBXO34 | c.358del p.I120Lfs*13 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- FBXO38 | c.1198del p.S400Pfs*35 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- FBXW8 | c.914A>G p.Y305C (on ENST00000309909; = p.Y343C on NM_012174.1) | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FCER1A | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGR2C | c.277C>A p.H93N | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by mutect2, varscan2
- FCRL6 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.223); called by muse, mutect2
- FGA | c.29T>A p.V10D | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2
- FGF14 | c.518del p.L173Wfs*3 | Frame Shift Del (DEL) | VAF 51/336 reads (15%) | called by mutect2, pindel, varscan2
- FGFRL1 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 66/381 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by mutect2, varscan2
- FHAD1 | c.4114C>T p.Q1372* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- FHOD3 | c.3089C>T p.A1030V (on ENST00000359247 / NM_001281739.3; = p.A1047V on NM_025135.5) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLCN | c.1301-1G>T p.X434_splice | Splice Site (SNP) | VAF 87/508 reads (17%) | called by muse, mutect2, varscan2
- FNDC4 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
961 further variants in this file (398 protein-altering or splice-affecting, 341 silent, 222 other) are not listed here.
